Somatic mutation profile of tumor specimen C3L-02964-01 (aliquot CPT0197210006) from CPTAC case C3L-02964, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.0 years (21,194 days).
Specimen C3L-02964-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cd27054-0980-4a56-b397-3c11c46bc6de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02964-31 (Blood Derived Normal), aliquot CPT0199140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d8a216b-df23-456c-af22-4d1316a2b5b5

The open-access MAF lists 256 somatic variants for this specimen: 168 protein-altering or splice-affecting, 50 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 50, Intron 21, Nonsense Mutation 13, Splice Site 4, 3'Flank 4, RNA 4, Frame Shift Del 4, 3'UTR 3, 5'UTR 3, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OAT | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121965039, CM920515, COSV64348003; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.277del p.L93Cfs*30 | Frame Shift Del (DEL) | VAF 35/214 reads (16%) | catalogued as rs1567556123, COSV53525400; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADAT | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765548846; called by muse, mutect2, varscan2
- ALOXE3 | c.1914C>A p.N638K | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.474); catalogued as rs370435985; called by mutect2, varscan2
- ATP10A | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63518239; called by muse, mutect2, varscan2
- ATP8B2 | c.1661A>G p.H554R (on ENST00000672630; = p.H521R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1480972424; called by muse, mutect2
- BRWD1 | c.3128A>G p.Y1043C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs976045629; called by muse, mutect2, varscan2
- C20orf173 | c.398G>A p.W133* (on ENST00000246199; = p.W186* on NM_001145350.2) | Nonsense Mutation (SNP) | VAF 20/215 reads (9%) | catalogued as rs1224392058; called by muse, mutect2
- CCS | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100040245; called by muse, mutect2, varscan2
- CDH10 | c.2278C>A p.Q760K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100052094, COSV99072653; called by muse, mutect2
- CEP170B | c.890G>A p.R297Q (on ENST00000453495; = p.R226Q on NM_015005.3) | Missense Mutation (SNP) | VAF 97/633 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs370520394; called by muse, mutect2, varscan2
- CNTNAP3 | c.2909G>T p.R970L | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs528416073, COSV99905323; called by muse, mutect2, varscan2
- CSMD2 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs901155048, COSV53897001; called by muse, mutect2, varscan2
- CSMD3 | c.2602C>A p.Q868K (on ENST00000297405 / NM_001363185.1; = p.Q764K on NM_052900.3) | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52271738; called by muse, mutect2
- CSMD3 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.19); catalogued as COSV52198600, COSV52260826; called by muse, mutect2, varscan2
- FBRSL1 | c.2935G>A p.A979T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs867066914; called by muse, mutect2, varscan2
- FLNC | c.4133C>T p.A1378V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748008658, COSV57961985; ClinVar: uncertain significance; called by muse, mutect2
- FREM2 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.828); catalogued as rs1296195130; called by muse, mutect2, varscan2
- GLRA3 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as COSV56867708; called by muse, mutect2
- GPR1 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV67977084; called by muse, mutect2
- GPR42 | c.615C>A p.S205R | Missense Mutation (SNP) | VAF 66/612 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1382728692; called by muse, mutect2, varscan2
- HHIPL1 | c.1030G>T p.G344* | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | catalogued as COSV100415250, COSV58090188; called by muse, mutect2, varscan2
- IGF1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61034362; called by muse, mutect2, varscan2
- ITGAE | c.1410G>T p.K470N | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53996164; called by muse, mutect2, varscan2
- KCNB2 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 20/205 reads (10%) | catalogued as COSV73049820; called by muse, mutect2, varscan2
- KCNJ3 | c.614G>T p.R205M | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54544522; called by muse, mutect2, varscan2
- KCNV1 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV52089100; called by muse, mutect2, varscan2
- LAMA2 | c.2054T>G p.L685R | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs746641607; called by muse, mutect2, varscan2
- LILRA5 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747186464; called by muse, mutect2, varscan2
- MALRD1 | c.5861G>T p.C1954F | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs915512008, COSV63196575; called by muse, mutect2, varscan2
- MRGPRX4 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs751740321; called by muse, mutect2, varscan2
- MS4A10 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.722); catalogued as rs1482741851; called by muse, mutect2, varscan2
- NBPF3 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 44/327 reads (13%) | catalogued as rs201803384, COSV59062383; called by muse, mutect2, varscan2
- NOLC1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53386227; called by muse, mutect2, varscan2
- NQO2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs373177858; called by muse, mutect2
- NTRK3 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62302761; called by muse, mutect2, varscan2
- OBSCN | c.22946C>A p.P7649H | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1226219847; called by muse, mutect2, varscan2
- OR6T1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189625, COSV58305658; called by muse, mutect2, varscan2
- OR8G1 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as rs1365345983; called by muse, mutect2, varscan2
- PAPPA | c.3998G>T p.G1333V | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60277514; called by muse, mutect2, varscan2
- PCSK9 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372165281, COSV56161201; ClinVar: uncertain significance; called by muse, mutect2
- PHLPP1 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.03); catalogued as rs1416501053; called by muse, mutect2, varscan2
- RAPGEF5 | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs1297716604; called by muse, mutect2, varscan2
- SCN1A | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM113267; called by muse, mutect2, varscan2
- SCN5A | c.393-2A>T p.X131_splice | Splice Site (SNP) | VAF 20/119 reads (17%) | catalogued as rs1312714061; called by muse, mutect2, varscan2
- SGCE | c.313G>A p.G105R (on ENST00000647096; = p.G69R on NM_003919.3) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as rs754959062; called by muse, mutect2, varscan2
- SI | c.2965C>G p.R989G | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100017576; called by muse, mutect2
- TACC2 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1267690614; called by muse, mutect2
- TBC1D8 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs775313531, COSV65212274, COSV65215055; called by muse, mutect2
- TECTA | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs928587604, COSV99881722; called by muse, mutect2, varscan2
- TEP1 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52989250; called by muse, mutect2, varscan2
- UGT2B11 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753403511; called by muse, mutect2, varscan2
- UNC13A | c.2764C>A p.R922S | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99409764; called by muse, mutect2, varscan2
- UNC5D | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 122/214 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99772269; called by muse, mutect2, varscan2
- XRCC1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1396631820, COSV53452541; called by muse, mutect2, varscan2
- ZNF708 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 19/196 reads (10%) | catalogued as rs780473497; called by muse, mutect2, varscan2
- ACSS3 | c.646C>G p.P216A | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS12 | c.4072A>G p.K1358E | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ADAMTS20 | c.5141C>A p.T1714N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2
- ADRA2A | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- AHCYL2 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG1L2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 89/494 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ANHX | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7622A>T p.Q2541L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ANKRD26 | c.2277G>T p.K759N | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- APBB1IP | c.752C>G p.T251R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- APCS | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- ARHGEF37 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ATP1A4 | c.1076T>A p.M359K | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GALT2 | c.741T>G p.Y247* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- BOK | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- BTBD3 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1H | c.5106G>C p.E1702D | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CCDC168 | c.13842G>C p.L4614F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- CCDC89 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCT8L2 | c.968T>A p.I323N | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- CDC45 | c.1327G>T p.G443W | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP74 | c.4211C>A p.P1404H | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, varscan2
- CHD7 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- COLEC12 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DAAM2 | c.3167A>G p.E1056G (on ENST00000274867 / NM_001201427.2; = p.E1055G on NM_015345.3) | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DMP1 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 75/518 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DOCK11 | c.5336G>T p.G1779V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK4 | c.5708A>G p.Y1903C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSC1 | c.896A>T p.D299V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DSEL | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUOX2 | c.3746A>G p.Y1249C | Missense Mutation (SNP) | VAF 80/638 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by mutect2, varscan2
- ELMOD2 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- EPHA5 | c.1750A>T p.I584F | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); called by muse, mutect2
- ERICH6 | c.550T>G p.S184A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRY | c.2780A>T p.K927I | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- GABRP | c.275G>T p.W92L | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GOLGB1 | c.5671G>A p.V1891I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- GRIA3 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- INO80D | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- INTS3 | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- IQCD | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KALRN | c.8404T>G p.L2802V (on ENST00000360013 / NM_001024660.4; = p.L1105V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KMT2D | c.4654G>C p.D1552H | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LIN28B | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAG | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED23 | c.668-1G>T p.X223_splice | Splice Site (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- MROH2B | c.3458C>G p.T1153S | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYH3 | c.3133_3152del p.L1045Efs*22 | Frame Shift Del (DEL) | VAF 56/412 reads (14%) | called by mutect2, pindel
- MYLIP | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 48/350 reads (14%) | called by muse, mutect2, varscan2
- N4BP2L2 | c.2484G>T p.Q828H (on ENST00000674422; = p.Q399H on NM_033111.4) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- N4BP2L2 | c.2483A>T p.Q828L (on ENST00000674422; = p.Q399L on NM_033111.4) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NAV3 | c.5335G>A p.G1779S | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, varscan2
- NBAS | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); called by muse, mutect2
- NES | c.4402C>A p.P1468T | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- NF1 | c.1426A>T p.K476* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- NOL4L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NPAP1 | c.2919del p.N974Mfs*34 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | called by mutect2, pindel, varscan2
- NPR1 | c.1605G>T p.G535= | Splice Region (SNP) | VAF 47/250 reads (19%) | called by muse, mutect2, varscan2
- NRG1 | c.177C>G p.I59M (on ENST00000523534; = p.I206M on NM_013962.2) | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OBSCN | c.21473T>C p.L7158P | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPALIN | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OPHN1 | c.925_927del p.A309del | In Frame Del (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- OPN5 | c.1110T>A p.N370K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.413); called by muse, mutect2
- OSTF1 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDH15 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- PCDH17 | c.2546C>A p.T849N | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB1 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PCLO | c.7156C>T p.L2386F | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PDCL | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PDGFRB | c.1844T>C p.V615A | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PEAK1 | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGLYRP2 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PHACTR2 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PIEZO2 | c.7063T>A p.W2355R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POU6F2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPFIA2 | c.1835A>T p.H612L | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PXDNL | c.2576G>T p.C859F | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASA1 | c.437dup p.L146Ffs*12 | Frame Shift Ins (INS) | VAF 37/306 reads (12%) | called by mutect2, pindel, varscan2
- ROBO1 | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RSF1 | c.3838G>T p.E1280* | Nonsense Mutation (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- RYR2 | c.1045A>T p.M349L | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, varscan2
- SAMD9L | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SCAMP1 | c.472+1G>T p.X158_splice | Splice Site (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2, varscan2
- SCN3B | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 71/529 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- SENP3 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 10/322 reads (3%) | called by muse, mutect2
- SHANK1 | c.3734del p.G1245Afs*98 | Frame Shift Del (DEL) | VAF 20/175 reads (11%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.2872G>T p.V958F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A7 | c.2871G>T p.M957I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SPEG | c.4160A>T p.E1387V | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SSBP4 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ST6GAL2 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 10/105 reads (10%) | PolyPhen possibly damaging (0.863); called by muse, mutect2
- ST8SIA3 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 26/213 reads (12%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL4 | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TARBP1 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR3 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7A | c.2777G>A p.R926K | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TM9SF4 | c.1201T>C p.Y401H | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS15 | c.1399G>C p.V467L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, varscan2
- TRAV26-1 | c.222T>A p.N74K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TRBV2 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- TTC39B | c.529G>C p.V177L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); called by muse, mutect2
- TYW5 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UBC | c.1904_1905insT p.K635Nfs*7 | Frame Shift Ins (INS) | VAF 60/463 reads (13%) | called by mutect2, pindel, varscan2
- VPS39 | c.2005G>T p.E669* (on ENST00000348544 / NM_001301138.2; = p.E658* on NM_015289.5) | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | called by mutect2, varscan2
- WASHC4 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- ZAR1 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP42 | c.896A>G p.H299R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF518A | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF611 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF841 | c.2240G>C p.C747S (on ENST00000426391 / NM_001369830.1; = p.C863S on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS20 | c.5142C>A p.T1714= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ADCY4 | c.1533C>G p.T511= | Silent (SNP) | VAF 47/309 reads (15%) | called by muse, mutect2, varscan2
- ARAP3 | c.4089C>T p.L1363= | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs758147299; called by muse, varscan2
- C1QL2 | c.222C>A p.I74= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as rs895095336; called by muse, mutect2, varscan2
- CLEC5A | c.84A>T p.P28= | Silent (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2, varscan2
- CNTN5 | c.2121A>G p.Q707= | Silent (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.3750G>A p.V1250= | Silent (SNP) | VAF 36/1218 reads (3%) | catalogued as rs1165017151; called by muse, mutect2
- COPB2 | c.117G>T p.V39= | Silent (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- DOCK6 | c.5970C>T p.A1990= | Silent (SNP) | VAF 49/327 reads (15%) | called by muse, mutect2, varscan2
- EDEM3 | c.87C>T p.C29= | Silent (SNP) | VAF 61/443 reads (14%) | catalogued as rs1347169579; called by muse, mutect2, varscan2
- FKBP6 | c.957C>A p.G319= | Silent (SNP) | VAF 98/570 reads (17%) | catalogued as COSV52720061; called by muse, mutect2, varscan2
- GRIN2B | c.810T>C p.P270= | Silent (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- HMCN2 | c.10593C>G p.P3531= | Silent (SNP) | VAF 56/287 reads (20%) | called by muse, mutect2, varscan2
- IBA57 | c.717G>T p.V239= | Silent (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2
- INTS14 | c.576G>T p.L192= (on ENST00000313182 / NM_001366360.2; = p.L113= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- KCNJ12 | c.471G>T p.V157= | Silent (SNP) | VAF 36/250 reads (14%) | called by muse, mutect2, varscan2
- KCNJ3 | c.615G>A p.R205= | Silent (SNP) | VAF 39/328 reads (12%) | catalogued as rs753335201, COSV99716703; called by muse, mutect2, varscan2
- KRT1 | c.309C>T p.G103= | Silent (SNP) | VAF 45/380 reads (12%) | catalogued as rs529661171; called by muse, mutect2, varscan2
- KRT79 | c.198G>A p.G66= | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as rs761692317; called by muse, mutect2, varscan2
- LIG1 | c.2506C>T p.L836= | Silent (SNP) | VAF 82/810 reads (10%) | called by muse, mutect2, varscan2
- LONRF3 | c.1296G>T p.T432= (on ENST00000371628 / NM_001031855.3; = p.T391= on NM_024778.5) | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2
- MGAT4B | c.1635A>G p.K545= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs1398911326; called by muse, mutect2, varscan2
- MUC5AC | c.15156C>T p.F5052= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- NADK2 | c.249G>A p.E83= | Silent (SNP) | VAF 149/559 reads (27%) | called by muse, mutect2, varscan2
- NSUN6 | c.417A>G p.S139= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as rs1346662999; called by muse, mutect2, varscan2
- PCDHB10 | c.274C>A p.R92= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV53384983; called by mutect2, varscan2
- PLXNA4 | c.681T>A p.I227= | Silent (SNP) | VAF 35/193 reads (18%) | called by muse, mutect2, varscan2
- RASGEF1C | c.102G>A p.L34= | Silent (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- RDH12 | c.558C>T p.H186= | Silent (SNP) | VAF 92/611 reads (15%) | catalogued as rs116465785, COSV50822264; called by muse, mutect2, varscan2
- RIPK2 | c.102C>G p.S34= | Silent (SNP) | VAF 36/576 reads (6%) | called by muse, mutect2
- SCN7A | c.2829T>G p.V943= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- SHROOM4 | c.1392A>T p.T464= | Silent (SNP) | VAF 76/226 reads (34%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.126G>A p.Q42= | Silent (SNP) | VAF 49/362 reads (14%) | called by muse, mutect2, varscan2
- SKI | c.753C>T p.R251= | Silent (SNP) | VAF 86/815 reads (11%) | catalogued as rs1383545325; called by muse, mutect2, varscan2
- SLC27A6 | c.1344G>A p.L448= | Silent (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- SLC7A1 | c.384A>T p.V128= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV66330864; called by muse, mutect2, varscan2
- SORCS1 | c.120G>T p.S40= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SP5 | c.18C>A p.V6= | Silent (SNP) | VAF 89/630 reads (14%) | catalogued as rs922346060; called by muse, mutect2, varscan2
- ST18 | c.1614A>T p.P538= | Silent (SNP) | VAF 35/283 reads (12%) | called by mutect2, varscan2
- SYNJ2BP | c.174G>C p.R58= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- TACC2 | c.1677C>T p.S559= | Silent (SNP) | VAF 30/350 reads (9%) | catalogued as rs1468646591; called by muse, mutect2
- TGM7 | c.1743C>T p.L581= | Silent (SNP) | VAF 33/263 reads (13%) | catalogued as COSV71772584; called by muse, mutect2, varscan2
- TMC1 | c.1338T>C p.I446= | Silent (SNP) | VAF 39/248 reads (16%) | catalogued as rs1250372748, COSV52786203; called by muse, mutect2, varscan2
- TRH | c.357A>G p.R119= | Silent (SNP) | VAF 108/588 reads (18%) | called by muse, mutect2, varscan2
- TRIP13 | c.435C>A p.V145= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- VPS8 | c.849A>G p.E283= (on ENST00000625842 / NM_001349294.1; = p.E281= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- WNT10B | c.978C>T p.S326= | Silent (SNP) | VAF 69/428 reads (16%) | called by muse, mutect2, varscan2
- WWOX | c.525C>A p.A175= | Silent (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2
- XIRP1 | c.2361T>C p.H787= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs763585832, COSV61138152; called by muse, mutect2
- ZNRF4 | c.354G>C p.A118= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as COSV55773026; called by muse, mutect2, varscan2
- ABCA7 | c.499-41G>T | Intron (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- ABHD4 | chr14:22598231 C>A | 5'Flank (SNP) | VAF 38/278 reads (14%) | catalogued as rs1284876910; called by muse, mutect2, varscan2
- ACP4 | chr19:50799489 C>A | 3'Flank (SNP) | VAF 37/255 reads (15%) | called by muse, mutect2, varscan2
- ACTB | c.-27-20G>T | Intron (SNP) | VAF 94/520 reads (18%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99204231 G>T | 3'Flank (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- AGBL4 | c.34+28612C>A | Intron (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- AKAP6 | c.*117A>G | 3'UTR (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2, varscan2
- BHLHE22 | c.-14G>T | 5'UTR (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- CHIT1 | c.*527C>A | 3'UTR (SNP) | VAF 40/333 reads (12%) | called by muse, mutect2, varscan2
- COL18A1 | c.3928+683A>T | Intron (SNP) | VAF 87/602 reads (14%) | called by muse, varscan2
- COMMD4 | c.3+111G>C | Intron (SNP) | VAF 13/160 reads (8%) | catalogued as rs1186105251; called by muse, mutect2
- COPS5 | c.143+433A>T | Intron (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- DLGAP1 | c.1591+73082G>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- DPY19L2P1 | n.3317C>A | RNA (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- ERI3 | c.831+788C>T | Intron (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- EYS | c.1767-8539T>A | Intron (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- FCRL1 | c.1186+90A>T | Intron (SNP) | VAF 18/348 reads (5%) | catalogued as rs1453166460; called by muse, mutect2
- GGA1 | c.43+204G>T | Intron (SNP) | VAF 44/317 reads (14%) | called by muse, mutect2, varscan2
- GPM6A | c.37+24823G>T | Intron (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- IGKV2D-26 | c.-9C>T | 5'UTR (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.927+44C>T | Intron (SNP) | VAF 40/457 reads (9%) | catalogued as rs769172506; called by muse, mutect2
- LINC01164 | n.1062G>T | RNA (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- LINC01193 | n.825T>C | RNA (SNP) | VAF 46/382 reads (12%) | called by muse, mutect2, varscan2
- LIPT2 | chr11:74497997 C>G | 5'Flank (SNP) | VAF 12/72 reads (17%) | catalogued as rs1265313124; called by muse, mutect2, varscan2
- LRRC37A6P | n.2768G>A | RNA (SNP) | VAF 84/475 reads (18%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41447A>T | Intron (SNP) | VAF 28/184 reads (15%) | catalogued as COSV100636423; called by muse, mutect2, varscan2
- PRSS1 | c.*30C>T | 3'UTR (SNP) | VAF 22/247 reads (9%) | catalogued as COSV100298358; called by muse, mutect2
- PSTPIP1 | c.355-33G>A | Intron (SNP) | VAF 83/600 reads (14%) | catalogued as rs765795513; called by muse, mutect2, varscan2
- RGS6 | c.1369-11926G>T | Intron (SNP) | VAF 35/323 reads (11%) | called by muse, mutect2, varscan2
- RN7SL545P | chr15:22428426 C>A | 3'Flank (SNP) | VAF 26/200 reads (13%) | called by mutect2, varscan2
- SDK1 | c.5828-5838A>T | Intron (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- SPDYE1 | chr7:44013570 del G | 3'Flank (DEL) | VAF 18/128 reads (14%) | called by mutect2, varscan2
- SREBF2 | c.2739-13G>T | Intron (SNP) | VAF 74/558 reads (13%) | called by muse, mutect2, varscan2
- ST3GAL6 | c.-157C>T | 5'UTR (SNP) | VAF 20/255 reads (8%) | called by muse, mutect2
- STAU2 | chr8:73747416 T>G | 5'Flank (SNP) | VAF 42/418 reads (10%) | called by muse, mutect2
- TRPA1 | c.2295+41A>T | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.10360+5466G>T | Intron (SNP) | VAF 47/286 reads (16%) | called by muse, mutect2, varscan2
- TUBB3 | c.278-307A>C | Intron (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
